TCGA case TCGA-FG-8185 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fb3884df-3680-4c5b-8092-981007aeba03

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 37 years; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, anaplastic: ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 37.3 years (13,621 days); Year of diagnosis: 2012; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 433 days (1.2 years); First symptom longest duration: 91-180 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Frontal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 21 days; Days to treatment end: 70 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 26 days; Days to treatment end: 70 days; Treatment dose: 5,940 cGy; Treatment outcome: Stable Disease; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 97 days; Days to treatment end: 412 days (1.1 years); Treatment outcome: Complete Response.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.

Follow-up (3 entries)
- Day 21 (prior to adjuvant therapy): Karnofsky performance status: 90.
- Days to follow up: 70 days; Disease response: Tumor Free.
- Days to follow up: 433 days (1.2 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache / Vision Changes.
- Timepoint category: Adulthood; Comorbidities: Allergies; Risk factors: Allergy, Food, NOS.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FG-8185-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.9; Shortest dimension: 0.3.
  Slide TCGA-FG-8185-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-FG-8185-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-FG-8185-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FG-8185-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; History ionizing radiation to head: No; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Tumor site: Supratentorial, Frontal Lobe; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: Yes; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: 91 - 180 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: Yes; Allergy food diagnosis age: > 20 Years; Allergy animals insects diagnosis indicator: No; Family history brain tumor: No; Inherited genetic syndrome indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 433 days; disease-specific survival: no event (censored), 433 days; disease-free interval: no event (censored), 433 days; progression-free interval: no event (censored), 433 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FG-8185-01A-11D-2252-01): tumor purity 0.76, ploidy 4, whole-genome doublings 1.
